Somatic mutation profile of tumor specimen TCGA-DX-AB2W-01A (aliquot TCGA-DX-AB2W-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2W, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 62.8 years (22,951 days).
Specimen TCGA-DX-AB2W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5758a3f5-02d6-4500-9e99-5edcd1d35df5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2W-10A (Blood Derived Normal), aliquot TCGA-DX-AB2W-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5640d12-55c3-4fd2-ab94-cf09204a5549

The open-access MAF lists 146 somatic variants for this specimen: 116 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 28, Nonsense Mutation 5, Splice Site 5, Frame Shift Del 3, Splice Region 2, 5'Flank 1, In Frame Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3644C>G p.S1215C (on ENST00000404938 / NM_001163941.2; = p.S770C on NM_178559.6) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99327626, COSV99328845; called by muse, mutect2, varscan2
- AC006059.2 | c.1600C>A p.H534N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100045760; called by muse, mutect2, varscan2
- AKAP9 | c.6160C>T p.Q2054* (on ENST00000359028; = p.Q2022* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100662719, COSV62342123; called by muse, mutect2, varscan2
- ANKDD1A | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.816); catalogued as rs780408018, COSV100132731; called by muse, mutect2, varscan2
- ANXA13 | c.831+1G>A p.X277_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as rs1443212759, COSV99146485; called by muse, mutect2, varscan2
- ASTN2 | c.3079A>T p.K1027* (on ENST00000313400 / NM_001365069.1; = p.K976* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99941146; called by muse, mutect2
- ATP6AP1 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100870716; called by muse, mutect2, varscan2
- BACE1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100475219, COSV57285844; called by muse, mutect2, varscan2
- BAZ2B | c.2729A>C p.Q910P | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99681028; called by muse, mutect2, varscan2
- BIN3 | c.295A>C p.K99Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.286); catalogued as COSV99374203; called by muse, mutect2, varscan2
- BTBD17 | c.1296C>G p.H432Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100945371; called by muse, mutect2, varscan2
- C10orf90 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760735148, COSV52950749; called by muse, mutect2, varscan2
- CACNA1B | c.5383C>A p.L1795M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99498636; called by muse, mutect2, varscan2
- CACNA1F | c.4946G>C p.G1649A | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100545144; called by muse, mutect2, varscan2
- CCNF | c.1784G>T p.S595I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1025547205, COSV99563906; called by muse, mutect2, varscan2
- CDKN2A | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs138677674, CM994496, COSV58683123; called by muse, mutect2, varscan2
- CFAP206 | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100849667, COSV65810075; called by muse, mutect2, varscan2
- COIL | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs533878148, COSV53595142; called by muse, mutect2, varscan2
- CPNE4 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs756733844, COSV101456771, COSV70196761; called by muse, mutect2, varscan2
- CPNE4 | c.801T>A p.N267K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101456772; called by muse, mutect2, varscan2
- CRB2 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100749708, COSV100749730; called by muse, varscan2
- CSMD1 | c.10503T>G p.I3501M (on ENST00000520002; = p.I3500M on NM_033225.6) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1454287167, COSV100151245; called by muse, mutect2, varscan2
- CTU2 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.206); catalogued as COSV99966278; called by muse, mutect2, varscan2
- CYFIP2 | c.2248C>T p.R750C (on ENST00000616178 / NM_001291722.2; = p.R725C on NM_014376.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs535692197, COSV100557449; called by muse, mutect2, varscan2
- DDX24 | c.2048A>G p.N683S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs767359462, COSV100428059; called by muse, mutect2, varscan2
- DIPK1B | c.309G>A p.V103= | Splice Region (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100765483; called by muse, mutect2, varscan2
- DLEC1 | c.1088A>T p.E363V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV100343007; called by muse, mutect2, varscan2
- DVL1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1158843179, COSV101127578; called by muse, mutect2, varscan2
- EFNB3 | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872855; called by muse, mutect2
- EMP2 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764133828, COSV100852853; called by mutect2, varscan2
- EPO | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.354); catalogued as COSV99402631, COSV99402638; called by muse, mutect2, varscan2
- ETAA1 | c.1146T>G p.D382E | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV99712877; called by muse, mutect2
- FANCC | c.1533+1G>T p.X511_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100002799; called by muse, mutect2, varscan2
- FANCC | c.1533G>T p.L511= | Splice Region (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100002801; called by muse, mutect2, varscan2
- FOXP3 | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV100873211; called by muse, mutect2, varscan2
- FRAS1 | c.11080G>T p.A3694S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99354252; called by muse, mutect2
- FRMD3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100418949; called by muse, mutect2, varscan2
- GLCE | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55945676; called by muse, mutect2, varscan2
- GLIS1 | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV56544140; called by muse, mutect2, varscan2
- HEG1 | c.1750T>G p.S584A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV100230751; called by muse, mutect2, varscan2
- IFNA14 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.042); catalogued as COSV101207326; called by muse, mutect2, varscan2
- IL1RL2 | c.623T>A p.V208D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99960920; called by muse, mutect2, varscan2
- IMPDH2 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV100455121; called by muse, mutect2, varscan2
- INPP5A | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as rs201167385, COSV100704467; called by muse, mutect2, varscan2
- IRS4 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100929641; called by muse, mutect2, varscan2
- KANK1 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100619662, COSV100619982; called by muse, mutect2, varscan2
- KCNQ5 | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100572563, COSV59678151; called by muse, mutect2, varscan2
- KIF17 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs757612024, COSV56121237; called by muse, mutect2, varscan2
- KLHL11 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100044419; called by muse, mutect2, varscan2
- KLHL6 | c.1308C>A p.N436K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.216); catalogued as COSV100384876; called by muse, mutect2, varscan2
- LCT | c.2532G>T p.K844N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.039); catalogued as rs1405957248, COSV99929996; called by muse, mutect2, varscan2
- LYVE1 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99811135; called by muse, mutect2, varscan2
- MAP2K6 | c.792T>G p.F264L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100765111; called by muse, mutect2, varscan2
- MAP3K5 | c.809A>T p.Q270L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV62888298; called by muse, mutect2, varscan2
- MORN3 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100804488; called by muse, mutect2, varscan2
- MRGPRE | c.302C>G p.T101R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV101100046; called by muse, mutect2, varscan2
- MSLN | c.1230+1G>C p.X410_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99558482; called by muse, mutect2, varscan2
- MTHFR | c.1437C>G p.I479M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV100453743; called by muse, mutect2, varscan2
- MUC5B | c.16680G>C p.Q5560H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV101500575; called by muse, mutect2, varscan2
- MYH7B | c.2696C>G p.A899G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.149); catalogued as COSV99483063; called by muse, mutect2, varscan2
- MYH9 | c.5388G>C p.E1796D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV99339376; called by muse, mutect2, varscan2
- NAALAD2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100428652; called by muse, varscan2
- NDFIP2 | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99519388; called by muse, mutect2, varscan2
- OR2Y1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100322813, COSV57137897; called by muse, mutect2, varscan2
- OR5H14 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV71193410; called by muse, mutect2, varscan2
- PDE1C | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs202172020, COSV100373172; called by muse, mutect2, varscan2
- PLA2G2D | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100908038; called by muse, mutect2, varscan2
- PLCH1 | c.5045A>G p.D1682G (on ENST00000340059 / NM_001130960.2; = p.D1674G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.223); catalogued as rs1462497046, COSV100397606; called by muse, mutect2, varscan2
- PLCXD1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.038); catalogued as rs747314505, COSV100397796; called by muse, mutect2, varscan2
- PPP2R2A | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100277304; called by muse, mutect2, varscan2
- PRTG | c.3380G>T p.G1127V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101221441; called by muse, mutect2, varscan2
- PSG1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99740200; called by muse, mutect2, varscan2
- RAB2A | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs1310015226, COSV99389939; called by muse, mutect2, varscan2
- RASSF7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.351); catalogued as COSV100272699; called by muse, mutect2, varscan2
- REPIN1 | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101262665; called by muse, mutect2
- RHOBTB1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs775273962, COSV61959776; called by muse, mutect2, varscan2
- RIMS2 | c.293C>G p.T98R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101344667; called by muse, mutect2, varscan2
- RP9 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs780856926, COSV99778018; called by muse, mutect2, varscan2
- RSPH14 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as rs941583483, COSV99321015, COSV99321057; called by muse, mutect2, varscan2
- SCGB2A2 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99929349; called by muse, mutect2, varscan2
- SCN4A | c.3088C>A p.H1030N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV101438576; called by muse, mutect2, varscan2
- SEL1L2 | c.850A>T p.I284L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99532984; called by muse, mutect2, varscan2
- SEMG1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs377393231; called by muse, mutect2, varscan2
- SETD6 | c.338G>T p.R113L (on ENST00000219315 / NM_001160305.4; = p.R89L on NM_024860.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs780113702, COSV99262375; called by muse, varscan2
- SHROOM3 | c.5692C>A p.L1898M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99934889; called by muse, mutect2, varscan2
- SLC7A14 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99200701; called by muse, mutect2, varscan2
- SLCO1B1 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99918821; called by muse, mutect2, varscan2
- SPATA19 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs754293828, COSV100141200; called by muse, mutect2, varscan2
- SPHKAP | c.3112T>G p.F1038V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100764289; called by muse, mutect2
- SPTBN2 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as rs143795261; called by muse, varscan2
- ST8SIA3 | c.413T>A p.F138Y | Missense Mutation (SNP) | VAF 21/38 reads (55%) | PolyPhen benign (0.066); catalogued as rs1264609704, COSV100129621, COSV60655694; called by muse, mutect2, varscan2
- STAT1 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs527393923, COSV63117315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT6 | c.441G>A p.M147I (on ENST00000610222 / NM_001366225.1; = p.M62I on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs543454369, COSV101059663; called by muse, varscan2
- TAF1L | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99645084; called by muse, mutect2, varscan2
- TAF2 | c.3158A>G p.D1053G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs753855640, COSV100978768; called by muse, mutect2, varscan2
- TANGO6 | c.2350C>T p.H784Y | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55763947; called by muse, mutect2, varscan2
- THSD7A | c.2828A>T p.K943I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV101448811; called by muse, mutect2, varscan2
- TNK2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100361523, COSV100361664; called by muse, mutect2, varscan2
- TRIM69 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.6); PolyPhen benign (0.265); catalogued as COSV100274353; called by muse, mutect2, varscan2
- TRPV3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as rs768586425, COSV100027953; called by muse, mutect2, varscan2
- UGT2B17 | c.784T>A p.Y262N | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV100497262; called by muse, mutect2, varscan2
- UPF2 | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV100707369; called by muse, mutect2, varscan2
- USH1G | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs745713548, COSV100140565, COSV100140626; called by muse, mutect2, varscan2
- UVRAG | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as COSV100638508; called by muse, mutect2, varscan2
- VWF | c.7352G>T p.C2451F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM163364, COSV99779630; called by muse, mutect2, varscan2
- WDTC1 | c.2000G>C p.S667T (on ENST00000319394 / NM_001276252.2; = p.S666T on NM_015023.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV100089252; called by muse, mutect2, varscan2
- ZAN | c.2795A>G p.E932G | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100769975; called by muse, mutect2, varscan2
- ATRX | c.6372_6375del p.N2125Wfs*2 | Frame Shift Del (DEL) | VAF 90/225 reads (40%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.8357_8368del p.D2786_D2789del | In Frame Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- FCGR2B | c.315_363delinsTGACAGCGGGGAGTACTCGTGCCAGACTGACCA p.N106Dfs*16 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2*
- FOXD4L4 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by mutect2, varscan2
- KIAA1549 | c.4229_4229+6delinsC p.X1410_splice | Splice Site (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2*
- OCEL1 | c.779_*1del | Nonstop Mutation (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- OPTN | c.1082_1094del p.L361Wfs*22 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.2193-2_2199del p.X731_splice (on ENST00000393800 / NM_001352375.2; = p.X651_splice on NM_018312.5) | Splice Site (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel
- AHCYL1 | c.558A>G p.V186= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100779629; called by muse, mutect2, varscan2
- ARHGAP21 | c.1749T>C p.F583= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1476427332, COSV100256463; called by muse, mutect2
- CDH4 | c.2331C>A p.R777= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs377265888, COSV100849320; called by muse, mutect2, varscan2
- CEACAM8 | c.930G>A p.R310= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs144424224; called by muse, mutect2, varscan2
- F5 | c.492C>T p.D164= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV100889185; called by muse, mutect2, varscan2
- GCNT3 | c.633A>G p.E211= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV101251855; called by muse, mutect2, varscan2
- HTR2C | c.189A>T p.I63= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52210333, COSV99350232; called by muse, mutect2, varscan2
- IL17RE | c.60C>G p.L20= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as COSV99925148; called by muse, mutect2, varscan2
- KIF19 | c.759C>A p.G253= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100739128; called by muse, mutect2
- MED13L | c.6048T>C p.D2016= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1176476865, COSV99929559; called by muse, mutect2, varscan2
- NAALAD2 | c.2130C>T p.N710= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs777380852, COSV100428650; called by muse, varscan2
- NCR1 | c.375C>A p.T125= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52556799, COSV99401065; called by muse, mutect2, varscan2
- NOTCH3 | c.6690C>A p.P2230= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99658135; called by muse, mutect2, varscan2
- NOX5 | c.2241G>A p.K747= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99534415; called by muse, mutect2
- OR4F17 | c.405C>A p.V135= | Silent (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- OR5F1 | c.417C>A p.T139= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs201523946, COSV53546357, COSV99558312; called by muse, mutect2, varscan2
- PADI2 | c.798C>A p.V266= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV64945593; called by muse, mutect2, varscan2
- PLEKHG4 | c.1053C>G p.L351= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV100846516; called by muse, mutect2, varscan2
- PRAMEF12 | c.420T>G p.G140= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV100743441; called by muse, mutect2, varscan2
- RAPSN | c.1119G>A p.K373= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as rs1048200516, COSV100100311; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN11A | c.174C>A p.A58= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100181092, COSV100182034; called by muse, mutect2, varscan2
- SDR9C7 | c.906A>G p.L302= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs1293930414, COSV99524662; called by muse, mutect2
- SLC39A7 | c.828A>G p.S276= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100807794; called by muse, mutect2
- STAB1 | c.249C>A p.S83= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV100401995; called by muse, mutect2, varscan2
- TENM2 | c.4047G>A p.K1349= (on ENST00000518659 / NM_001122679.2; = p.K1110= on NM_001080428.3) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV101319167; called by muse, mutect2, varscan2
- UNCX | c.339C>G p.T113= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV100310287, COSV60332931, COSV60333656; called by muse, mutect2, varscan2
- VAT1L | c.30G>A p.E10= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV100213892; called by mutect2, varscan2
- ZNF354A | c.1338C>T p.A446= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100234577, COSV59983598; called by muse, mutect2, varscan2
- FAM74A3 | n.169G>T | RNA (SNP) | VAF 46/409 reads (11%) | called by muse, mutect2, varscan2
- RHBG | chr1:156367786 C>A | 5'Flank (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
